Surgical pathology report (de-identified scan), TCGA case TCGA-30-1866, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Harvard, specimen TCGA-30-1866-01A (Primary Tumor).

[page 1 of 3]
Accession Number: [REDACTED]
Type: Surgical Pathology
Pathology Report [REDACTED] OMENTUM BIOPSY
Accessioned On: [REDACTED]

Report Status: Final

TCGA-30-1866

DIAGNOSIS: [REDACTED]
SPECIMEN LABELED "OMENTAL BIOPSY" (including FSA):
METASTATIC PAPILLARY SEROUS CARCINOMA.

SPECIMEN LABELED "RECTUS MUSCLE BIOPSY":
Gross only for tissue allocation.
No microscopic exam.

SPECIMEN LABELED "OMENTECTOMY TUMOR":
METASTATIC PAPILLARY SEROUS CARCINOMA.

SPECIMEN LABELED "TUMOR ADJACENT TO SPLEEN":
METASTATIC PAPILLARY SEROUS CARCINOMA.

SPECIMEN LABELED "TUMOR FROM TRANSVERSE COLON":
METASTATIC PAPILLARY SEROUS CARCINOMA.

SPECIMEN LABELED "TUMOR ADJACENT TO LIVER":
METASTATIC PAPILLARY SEROUS CARCINOMA.

SPECIMEN LABELED "LEFT COLONIC GUTTER":
METASTATIC PAPILLARY SEROUS CARCINOMA.

SPECIMEN LABELED "ABDOMINAL WALL TUMOR":
METASTATIC PAPILLARY SEROUS CARCINOMA.

SPECIMEN LABELED "RIGHT ADNEXA MASS":
Ovary:
PAPILLARY SEROUS CARCINOMA, MODERATELY DIFFERENTIATED.
Tumor involves ovarian hilum and surface, see comment.

Fallopian tube:
Tumor is present in lumen.
See comment.

SPECIMEN LABELED "CUL DE SAC TUMOR":
METASTATIC PAPILLARY SEROUS CARCINOMA.

SPECIMEN LABELED "LEFT ADNEXA":
Ovary:
No significant pathologic change.

Fallopian tube:
PAPILLARY SEROUS CARCINOMA, in lumen.

SPECIMEN LABELED "SIGMOID TUMOR":
METASTATIC PAPILLARY SEROUS CARCINOMA.

Comment: The distribution is consistent with a primary peritoneal carcinoma.

CLINICAL DATA:

History: [REDACTED] with ascites, abdominal masses.
Clinical Diagnosis: Ovarian cancer.

TISSUE SUBMITTED: 1. Omentum biopsy.
2. Rectus muscle biopsy.
3. Omentectomy tumor.
4. Tumor adjacent to spleen.
5. Tumor from transverse colon.
6. Tumor adjacent to liver.

[page 2 of 3]
- 7. Left colonic gutter.
- 8. Abdominal wall tumor.
- 9. Right adnexa mass.
- 10. Cul-de-sac tumor.
- 11. Left adnexa.
- 12. Sigmoid tumor.

O.R. CONSULTATION:

SPECIMEN LABELED "1 OMENTAL BIOPSY"(FSA):

Serous carcinoma, consistent with ovarian origin.

GROSS DESCRIPTION:

The specimen is received fresh in twelve parts, labeled with the patient's and unit number.

Part one, "omental biopsy", consists of a single fragment of pink/tan soft tissue (8.0 x 5.5 x 3.5 cm) grossly consistent with tumor. A representative section is submitted for frozen section analysis as FSA. A representative section is submitted for microscopic examination.

Micro 1: FSAR, 1 fragment,

Micro 2: omental biopsy, 4 fragments,

Part two, "rectus muscle biopsy", consists of a single fragment of pink/tan soft tissue grossly consistent with skeletal muscle (2.4 x 1.5 x 0.9 cm). The entire specimen is submitted to for special studies.

Part three, "omentectomy tumor", consists of a 2104 gm portion of omentum (35 x 7.3 x 6.5 cm). The specimen is multi-lobulated tan/grey with areas of focal necrosis and degeneration. The specimen is grossly consistent with almost complete replacement of omentum by tumor. Little of any adipose tissue is grossly identifiable. Multiple fragments are submitted for microscopic examination.

Micro 3-5: 10 fragments,

Part four, "tumor adjacent to spleen", consists of a portion of adipose tissue with tumor implant, (7.4 x 6.3 x 3.5 cm). There are multiple tumor nodules (from 0.3 cm up to 2.8 cm in greatest dimension). Representative sections are submitted for microscopic examination.

Micro 6: tumor, fat, multiple fragments,

Part five, "tumor from transverse colon", consists of two fragments of yellow/grey/brown soft tissue, (4.7 x 3.7 x 2.2 cm, 4.8 x 4.5 x 2.3 cm). The specimens are composed of a mixture of adipose tissue and well-circumscribed and papillary nodules ranging in size from 0.3 cm up to 2.2 to 3.4 cm. Representative sections are submitted for microscopic examination. Nodules are grossly consistent with tumor seen in other specimen. There are areas of focal hemorrhage and likely necrosis.

Micro 7: tumor, transverse colon, multiple fragments,

Part six, "tumor adjacent to liver", consists of two grey/beige soft tissue fragments (5.7 x 3.5 x 2.4 cm, 3.2 x 2.5 x 1.0 cm). The suspected tumor nodules have a papillary surface and have a solid white friable parenchyma. Representative sections are submitted for microscopic examination.

Micro 8: tumor adjacent to liver, 5 fragment

Part seven, "left colonic gutter", consists of two fragments of grey/yellow soft tissue mass (3.9 x 2.3 x 1.7 cm, 1.3 x 0.9 x 0.3 cm). Both specimen have a nodular/somewhat papillary surface. One of the nodules is white and somewhat friable. Representative sections are submitted for microscopic examination.

Micro 9: left colonic gutter, 4 fragments,

Part eight, "abdominal wall tumor", consists of five fragments of grey/beige soft tissue masses (5.9 x 5.7 x 1.8 cm in aggregate). All of the fragments have a papillary nodular surface with a central white/beige friable center.

TCGA-30-1866

[page 3 of 3]
Representative sections are submitted for microscopic examination.

Micro 10: 4 fragments,

Part nine, "right adnexa mass", consists of multiple fragments of grey/beige papillary soft tissue (6.8 x 8.3 x 3.1 cm in aggregate). There are at least eight individual fragments ranging in size from 1.1 cm up to 5.1 cm. There is a possible portion of ovarian parenchyma (2.8 x 1.5 x 1.3 cm) which have a smooth glistening white, somewhat nodular cerebriform surface. A possible segment of fallopian tube and fimbria is grossly identified (2.8 cm in length x 0.8 cm diameter). Representative sections of the specimen are submitted for microscopic examination.

Note: The ovary does not appear to be completely intact and present.

Micro 11-12: possible ovary, fallopian tube, multiple fragments,

Micro 13-14: suspected tumor, multiple fragments,

Part ten, "cul-de-sac tumor", consists of at least six fragments of grey/beige soft tissue (6.0 x 4.0 x 3.2 cm in aggregate). The fragments of tissue have a papillary, friable surface with a white/grey friable interior. Multiple fragments are sample for microscopic examination.

Micro 15: 4 fragments,

Part eleven, "left adnexa", consists of an ovary (3.3 x 1.8 x 0.9 cm) and adjacent fimbriated fallopian tube (2.9 cm in length x 0.4 cm in diameter). The external surface of the ovary is smooth with areas of focal cerebriform nodularity. The ovarian parenchyma is grey/tan multi-coloured without focal cyst hemorrhage or necrosis. Representative section of this ovary are submitted for microscopic examination.

Micro 16-17: left adnexa, multiple fragments,

Part twelve, "sigmoid tumor", consists of two fragments of yellow/beige friable soft tissue (3.4 x 3.3 x 1.8 cm, 4.5 x 4.6 x 2.4 cm). The specimen has intermixed adipose tissue and nodules of papillary suspected tumor. Representative sections are submitted for microscopic examination.

Micro 18: 5 fragments,

Reports to:

SPECIMEN TYPE: OMENTUM BIOPSY

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE MASS OR SIMPLE EXCISION

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE MASS OR SIMPLE EXCISION

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE MASS OR SIMPLE EXCISION

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE MASS OR SIMPLE EXCISION

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE MASS OR SIMPLE EXCISION

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE MASS OR SIMPLE EXCISION

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE MASS OR SIMPLE EXCISION

ADDITIONAL SPECIMEN TYPE: OVARY WITH OR WITHOUT FALLOPIAN TUBE- NON-NEOPLAS

ADDITIONAL SPECIMEN TYPE: OVARY WITH OR WITHOUT FALLOPIAN TUBE- NON-NEOPLAS

Source: NCI Genomic Data Commons file 9282e06a-199a-438a-a288-71b68fdae2c9 (TCGA-30-1866.BDA3960C-1610-4BFF-B60E-B9C8F3A4454A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).